Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4170, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4170-01A (Primary Tumor).

[page 1 of 4]
.....

Clinical Diagnosis & History:

with left renal mass.

Specimens Submitted:

- 1: SP: Left kidney and adrenal
2: SP: Left peri-aortic lymph node

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL, LEFT; NEPHRECTOMY WITH ADRENALECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 5.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS BENIGN CORTICAL CYSTS.
- THE ADRENAL GLAND IS UNREMARKABLE.
- 2) LYMPH NODE, LEFT PERI-AORTIC; EXCISION:
- THIRTEEN BENIGN LYMPH NODES (0/13).
- [REDACTED]
- [REDACTED]

Gross Description:

1) The specimen is received fresh, labeled, "Left kidney and adrenal". It consists of a nephrectomy specimen along with adrenalectomy, with scant amount of perinephric adipose tissue. The kidney measures 11.5 x 7.5 x 5.0 cm, grossly unremarkable, adrenal gland measures 5.0 x 1.5 x 0.7 cm and a stump of ureter measuring 11.0 cm in length and 0.6 cm in average diameter. The kidney is bivalved, revealing a 5.0 x 4.0 x 3.0 cm subcapsular, yellow-tan, circumscribed tumor at the superior pole with minimal areas of hemorrhage and necrosis with a central scar. The tumor does not involve the pelvicalyceal system or vascular structures. The capsule is not easily peeled-off from the cortex. The rest of the renal parenchyma is unremarkable, except for a few cortical cysts (0.1-0.4 cm). At the hilum, grossly no lymph nodes are identified. Photographs are taken. Tissue is submitted for TPS and EM. The external surface is inked black.

Summary of Sections:

UM – ureteric margin
VM – vascular margin with surrounding adipose tissue
A – adrenal gland
TA – tumor with adrenal gland
TP – tumor with renal pelvis

[page 2 of 4]
T -- tumor
K -- uninvolved kidney

2) The specimen is received in formalin, labeled "Left peri-aortic lymph node". It consists of two pieces of fatty tissue measuring in aggregate 4.5 x 3.5 x 0.5 cm. Entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Left kidney and adrenal

Block	Sect. Site	PCs
1	A	3
1	K	1
5	T	5
1	TA	1
1	TP	1
1	UM	2
1	VM	2

Part 2: SP: Left peri-aortic lymph node

Block	Sect. Site	PCs
3	U	3

[page 3 of 4]
Clinical Diagnosis & History:

with left renal mass.

Specimens Submitted:

1: SP: Left kidney and adrenal

2: SP: Left peri-aortic lymph node

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL, LEFT; NEPHRECTOMY WITH ADRENALECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 5.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS BENIGN CORTICAL CYSTS.
- THE ADRENAL GLAND IS UNREMARKABLE.
- 2) LYMPH NODE, LEFT PERI-AORTIC; EXCISION:
- THIRTEEN BENIGN LYMPH NODES (0/13).

Gross Description:

1) The specimen is received fresh, labeled, "Left kidney and adrenal". It consists of a nephrectomy specimen along with adrenalectomy, with scant amount of perinephric adipose tissue. The kidney measures 11.5 x 7.5 x 5.0 cm, grossly unremarkable, adrenal gland measures 5.0 x 1.5 x 0.7 cm and a stump of ureter measuring 11.0 cm in length and 0.6 cm in average diameter. The kidney is bihalved, revealing a 5.0 x 4.0 x 3.0 cm subcapsular, yellow-tan, circumscribed tumor at the superior pole with minimal areas of hemorrhage and necrosis with a central scar. The tumor does not involve the pelvicalyceal system or vascular structures. The capsule is not easily peeled-off from the cortex. The rest of the renal parenchyma is unremarkable, except for a few cortical cysts (0.1-0.4 cm). At the hilum, grossly no lymph nodes are identified. Photographs are taken. Tissue is submitted for TPS and EM. The external surface is inked black.

Summary of Sections:

UM – ureteric margin

VM – vascular margin with surrounding adipose tissue

A – adrenal gland

TA – tumor with adrenal gland

TP – tumor with renal pelvis

[page 4 of 4]
T - tumor
K - uninvolved kidney

2) The specimen is received in formalin, labeled "Left peri-aortic lymph node". It consists of two pieces of fatty tissue measuring in aggregate 4.5 x 3.5 x 0.5 cm. Entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Left kidney and adrenal

Block	Sect. Site	PCs
1	A	3
1	K	1
5	T	5
1	TA	1
1	TP	1
1	UM	2
1	VM	2

Part 2: SP: Left peri-aortic lymph node (sr)

Block	Sect. Site	PCs
3	U	3

Source: NCI Genomic Data Commons file 54f6d593-0022-42bd-b0c9-25735192c93d (TCGA-BP-4170.2F591FE7-9E6F-4CD0-97EF-A9A0068289C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).